Somatic mutation profile of tumor specimen TCGA-UE-A6QU-01A (aliquot TCGA-UE-A6QU-01A-12D-A32I-09) from TCGA case TCGA-UE-A6QU, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleomorphic liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-UE-A6QU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9fc0327-7a66-4223-b8cf-44a1a8bcf6f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UE-A6QU-10B (Blood Derived Normal), aliquot TCGA-UE-A6QU-10B-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fcb3468-ea4f-4fd9-b7c3-2787ef2b7097

The open-access MAF lists 57 somatic variants for this specimen: 40 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 15, Frame Shift Del 3, 3'Flank 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM22 | c.590T>G p.L197W | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs775835621, COSV99717694; called by muse, mutect2, varscan2
- CAMKK1 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99340459; called by muse, mutect2, varscan2
- CCDC180 | c.2291A>G p.E764G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs146215337; called by muse, mutect2, varscan2
- CCN3 | c.665T>C p.M222T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as COSV99423204; called by muse, mutect2, varscan2
- DNAAF5 | c.1418C>A p.A473E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV99860089; called by mutect2, varscan2
- DNAH9 | c.4945C>A p.P1649T | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99306977; called by muse, mutect2, varscan2
- DST | c.19402G>A p.E6468K (on ENST00000361203 / NM_001374722.1; = p.E4165K on NM_015548.5) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.786); catalogued as COSV99752889, COSV99758397; called by muse, mutect2, varscan2
- ERCC8 | c.529T>A p.S177T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99410554; called by muse, mutect2, varscan2
- FAM189A2 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99975199; called by muse, mutect2, varscan2
- FAM47A | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.817); catalogued as COSV100649995, COSV60499941; called by muse, mutect2, varscan2
- FBLN2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as COSV99852306; called by muse, mutect2, varscan2
- FLT4 | c.2164T>A p.S722T | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99988043; called by muse, mutect2
- FMN2 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV100146472; called by muse, mutect2, varscan2
- FUT2 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101218128; called by muse, mutect2, varscan2
- GEMIN4 | c.2179G>C p.D727H | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100021498; called by muse, mutect2
- GRHPR | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as rs758049256, COSV100547057; called by muse, mutect2, varscan2
- LETM2 | c.1408G>A p.E470K (on ENST00000379957 / NM_001286819.2; = p.E375K on NM_144652.3) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.283); catalogued as COSV52687963; called by muse, mutect2, varscan2
- MAGEE2 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs769541561, COSV100973010, COSV100973116; called by muse, mutect2, varscan2
- NPM2 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99235774; called by muse, mutect2
- NPM2 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99235778; called by muse, varscan2
- NTSR1 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV100980678, COSV65139744; called by muse, mutect2, varscan2
- OR1S1 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770434407, COSV100515453; called by muse, mutect2, varscan2
- PHLPP1 | c.3536C>G p.T1179S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.802); catalogued as COSV99408815; called by muse, mutect2, varscan2
- PSG2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs777210176, COSV61545245; called by muse, mutect2, varscan2
- PTPRN | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs201131601, COSV55352818, COSV99834174; called by muse, mutect2, varscan2
- RIN2 | c.260C>G p.T87R (on ENST00000255006 / NM_001242581.1; = p.T38R on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV99657550; called by muse, mutect2
- RYR3 | c.6759C>G p.N2253K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV100774400, COSV63109887; called by muse, mutect2, varscan2
- SEPHS1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59257294, COSV59259817; called by muse, varscan2
- SLC5A5 | c.742G>C p.V248L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs776946606, COSV99715233; called by muse, mutect2, varscan2
- SLC8A3 | c.2698G>A p.A900T (on ENST00000381269 / NM_183002.3; = p.A898T on NM_033262.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs748544994, COSV99385719; called by muse, mutect2, varscan2
- SLK | c.1750T>G p.L584V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV100211925; called by muse, mutect2, varscan2
- SNX2 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101075784, COSV65349453; called by muse, mutect2
- THRA | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV99225690; called by muse, mutect2, varscan2
- TRPM6 | c.5900A>G p.H1967R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100666706; called by muse, mutect2, varscan2
- UNC5B | c.934T>A p.S312T | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100101042, COSV58974194; called by muse, mutect2, varscan2
- WDR24 | c.970C>T p.R324W (on ENST00000248142; = p.R194W on NM_032259.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99555477, COSV99555890; called by muse, mutect2, varscan2
- ZNF418 | c.574T>C p.C192R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV101268962; called by muse, mutect2, varscan2
- RTN4 | c.872_873del p.E291Vfs*29 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by pindel, varscan2
- SYT1 | c.555del p.L186Cfs*40 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- YBX2 | c.677del p.P226Hfs*22 | Frame Shift Del (DEL) | VAF 20/151 reads (13%) | called by mutect2, pindel, varscan2
- ACAD10 | c.1347C>G p.L449= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100564424; called by muse, mutect2, varscan2
- DNAH17 | c.5286C>T p.H1762= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs769705961, COSV101102945; called by muse, mutect2
- FAM13A | c.997T>C p.L333= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs989478205, COSV99984312; called by muse, mutect2, varscan2
- FBN3 | c.7308G>A p.L2436= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1390459017, COSV99561440; called by muse, mutect2, varscan2
- FBXL22 | c.465G>A p.E155= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100634427; called by muse, mutect2, varscan2
- GRM4 | c.2424C>G p.T808= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100946608; called by muse, mutect2, varscan2
- MRPL4 | c.834A>T p.S278= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV99460178; called by muse, mutect2, varscan2
- OTOP3 | c.210A>G p.Q70= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100172952; called by mutect2, varscan2
- PGAP6 | c.1770C>T p.C590= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as rs145807786; called by muse, mutect2, varscan2
- RARB | c.645C>T p.D215= (on ENST00000383772 / NM_001290216.2; = p.D208= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100412568, COSV100412699; called by muse, mutect2, varscan2
- STK38 | c.237G>A p.L79= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs1204304062, COSV100007436; called by muse, mutect2, varscan2
- TOLLIP | c.252G>A p.A84= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs779882402, COSV99719643; called by muse, varscan2
- TRIM7 | c.1209G>A p.V403= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV51240364; called by mutect2, varscan2
- TRIM7 | c.1038G>A p.L346= | Silent (SNP) | VAF 26/232 reads (11%) | catalogued as COSV99220324; called by muse, mutect2, varscan2
- ZNF10 | c.1503G>A p.K501= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99940100; called by muse, mutect2, varscan2
- LGR6 | c.213-11210G>A | Intron (SNP) | VAF 23/64 reads (36%) | catalogued as rs1301257455, COSV99707529; called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28580452 C>G | 3'Flank (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
